Surgical pathology report (de-identified scan), TCGA case TCGA-43-6773, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-6773-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Lymph node, L4, biopsy
- B. Lymph nodes, R4, biopsy
- C. Level 10 right lung
- D. Subcarinal right lung
- E. Right lower lobe and middle lobe

CLINICAL NOTES

CLINICAL HISTORY: Right lung mass.

FROZEN SECTION DIAGNOSIS

[REDACTED] nodes, L4, biopsy: Negative for malignancy. [REDACTED]

[REDACTED] nodes, R4, biopsy: Negative for malignancy. [REDACTED]

GROSS DESCRIPTION

A. The specimen is received fresh for frozen section labeled "L4 (right lung)" and consists of a 1.0 x 0.4 x 0.4 cm. aggregate of gray to tan tissue fragments entirely frozen as frozen section AFS1.

B. Received fresh labeled "B. R4 (right lung)" are 4 fragments of black to pink tissue measuring in aggregate of 2.0 x 1.0 x 0.5 cm. entirely frozen as frozen section BFS1. The piece is bisected.

C. Received fresh labeled "level 10" is a slightly fragmented and cauterized, 0.7 x 0.5 x 0.4 cm. gray black tissue in keeping with lymph node which is bisected and entirely submitted in one block. AS-1.

D. Received fresh labeled "subcarinal" are three irregular fragmented, gray-black tissues in keeping with lymph nodes measuring up to 2.0 cm. greatest dimension. The specimens are entirely submitted in four blocks as labeled. AS-4

BLOCK SUMMARY: 1, 2 - One bisected node per cassette; 3, 4 - bisected largest node (1/2 per cassette).

E. Received fresh labeled "right lower lobe and middle lobe" is a 400 gram, 14.5 x 12.0 x 7.5 cm. lobectomy specimen consisting of a portion of right middle lobe measuring 10.0 x 5.8 x 3.5 cm. and the entire lower lobe. A 1.5 cm. in length, 1.4 x 1.0 cm. in diameter bronchial stump is present. The pleura is smooth to slightly scabrous, tan-pink with a few tan-pink fibrous adhesions. A palpable peribronchial mass is evident. The overlying pleura is inked black. On sectioning, there is a moderately well-circumscribed, 9.0 x 6.4 x 5.8 cm. glistening to focally chalky tan-white tumor mass which focally abutts the bronchial stump (see block 3). The tumor also extends to within 0.2 cm. of the inked pleural surface. The tumor, located within the middle lobe grossly

[page 2 of 3]
[REDACTED]

extends to involve a matted group of perihilar lymph nodes (see block 7). A portion of the tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining parenchyma is spongiform, red-purple without additional mass lesion or abnormality. Five rubbery gray-black perihilar tissues in keeping with lymph nodes measuring up to 1.2 cm. in greatest dimension are recovered. Representative sections are submitted in 12 blocks as labeled. RS-12.

BLOCK SUMMARY: 1 - Brochial margin; 2 - vascular margins; 3 - tumor abutting bronchial stump; 4, 5 - tumor to inked pleural surface; 6 - tumor to normal; 7 - tumor to matted perihilar lymph nodes; 8, 9 - random from remainder of specimen; 10 - representative middle lobe with pleural adhesions; 11 - four whole nodes; 12 - one bisected

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A, B, C, D. Microscopic examination of the separately submitted lymph nodes reveals benign lymph node tissue with no metastatic tumor identified.

E. Microscopic examination of the right lower and middle lobe lung resection reveals -

Histologic type: Squamous cell carcinoma with some minimal glandular differentiation, predominantly nonkeratinized.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Tumor is 9 cm in greatest dimension and involves a major bronchus (pT2).

Margins of resection: Negative for tumor.

Direct extension of tumor: Into the bronchus, no diagnostic pleural invasion identified.

Venous (large vessel) invasion: Not identified.

Arterial (large vessel) invasion: Not identified.

Lymphatic (small vessel) invasion: Present.

Regional lymph nodes (pN): Tumor is identified in one of seven hilar lymph nodes. This tumor focus measures 1 cm in greatest dimension and appears to represent some direct extension of tumor into the hilar lymph node, but also shows lymphatic space invasion in this area. All of the separate lymph nodes are negative for tumor (pN1).

Distant metastasis (pM): Could not evaluate, pMX.

Other findings: Some intrapulmonary spread of tumor is identified slide E8 with tumor within pulmonary parenchyma and lymphatic spaces in the lung well away from the primary tumor. Also areas of emphysema are noted and chronic bronchitis and a focal area of pulmonary infarction versus possible focal organizing pneumonia is identified in slide E9. Some pulmonary hemorrhage and edema is noted in the middle lobe in slide E10.

3x4, 14x2, 5x1

DIAGNOSIS

- A. Lymph node, L4, biopsy: Negative for malignancy.
- B. Lymph nodes, R4, biopsy: Negative for malignancy.
- C. Lymph nodes, level 10, biopsy: Negative for malignancy.
- D. Lymph nodes, subcarinal, biopsy: Negative for malignancy.

[page 3 of 3]
[REDACTED]

E. Lung, right lower lobe and middle lobe, excision:
Squamous cell carcinoma, moderately differentiated, tumor size
9 cm
One of seven hilar lymph nodes is positive for squamous cell
carcinoma (1/7).
Lymphatic space invasion and intrapulmonary tumor spread
identified.
The pleura is negative for tumor, the resection margins are
negative for tumor.
See microscopic description for template details.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 85f142f2-ad7f-4da5-b10e-7b46e2984bf6 (TCGA-43-6773.B09E0471-A726-41B4-90ED-B9E1E062896D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).